Somatic mutation profile of tumor specimen TCGA-FC-7708-01A (aliquot TCGA-FC-7708-01A-11D-2114-08) from TCGA case TCGA-FC-7708, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.4 years (19,144 days).
Specimen TCGA-FC-7708-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f623e57a-5c89-4baa-aa2e-9b358de8dc84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-7708-10A (Blood Derived Normal), aliquot TCGA-FC-7708-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abff74af-b463-4cad-ac54-a3eff85d446c

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJC13 | c.2564A>G p.N855S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs387907571, CM141862, COSV53447403; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- CDH23 | c.9971A>C p.E3324A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV56453156; called by muse, mutect2, varscan2
- CHD7 | c.8397G>A p.M2799I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV71107864; called by muse, mutect2, varscan2
- DST | c.7948G>C p.D2650H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV55003476; called by muse, mutect2
- FRMD7 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100049153, COSV53745181; called by muse, mutect2, varscan2
- GABRB1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs751931636, COSV54974645; called by muse, mutect2, varscan2
- GPATCH4 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV58039332; called by muse, mutect2, varscan2
- HECTD4 | c.5488C>T p.L1830F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66388619; called by muse, mutect2
- KNL1 | c.3605G>A p.C1202Y (on ENST00000346991 / NM_170589.5; = p.C1176Y on NM_144508.5) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs377752647, COSV61152493; called by muse, mutect2, varscan2
- KRT85 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs529091727, COSV57736273; called by muse, mutect2, varscan2
- LRRC66 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58632571; called by muse, mutect2
- NID2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs147980330, COSV53496430; called by muse, mutect2, varscan2
- NUP107 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); catalogued as COSV57493729; called by muse, mutect2, varscan2
- SCN10A | c.3088-2A>G p.X1030_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV71860683; called by muse, mutect2, varscan2
- SLC16A13 | c.788T>A p.L263H | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57273911; called by muse, mutect2
- SNRPC | c.304A>T p.M102L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.267); catalogued as COSV55075042; called by muse, mutect2, varscan2
- TRAF5 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs113925874; called by muse, mutect2, varscan2
- ZNF146 | c.838A>T p.K280* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV61931383; called by muse, mutect2, varscan2
- H2BC8 | c.166_186del p.S56_I62del | In Frame Del (DEL) | VAF 30/288 reads (10%) | called by mutect2, pindel
- PCID2 | c.101del p.P34Lfs*33 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, pindel, varscan2
- RNF31 | c.1204dup p.D402Gfs*35 | Frame Shift Ins (INS) | VAF 42/382 reads (11%) | called by mutect2, pindel, varscan2
- EPHA7 | c.726G>A p.A242= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs148725762; called by muse, mutect2, varscan2
- FCGR2A | c.576C>A p.G192= (on ENST00000271450 / NM_001136219.3; = p.G191= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV54837574; called by muse, mutect2, varscan2
- TMEFF2 | c.585C>T p.C195= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs779383447, COSV55829366, COSV55842410; called by muse, mutect2, varscan2
- VPS13C | c.423C>T p.N141= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as COSV51132451; called by muse, mutect2, varscan2
- ZAP70 | c.1038C>T p.C346= | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as rs758571157, COSV53853196; called by muse, mutect2, varscan2
